Somatic mutation profile of tumor specimen TCGA-GN-A9SD-06A (aliquot TCGA-GN-A9SD-06A-11D-A401-08) from TCGA case TCGA-GN-A9SD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.6 years (23,217 days).
Specimen TCGA-GN-A9SD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9abc9572-0b7c-451e-acee-5880987f2eee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A9SD-10A (Blood Derived Normal), aliquot TCGA-GN-A9SD-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ccfdfac-4a90-4a3a-8a00-e3c07b11265d

The open-access MAF lists 170 somatic variants for this specimen: 107 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 55, Nonsense Mutation 10, Intron 4, RNA 4, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 14/196 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2
- LAMA2 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs376088608, CM151370; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV101200934; called by muse, mutect2
- AC126283.2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1560546307, COSV101144024; called by muse, mutect2
- ACSM2B | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100312234; called by muse, mutect2, varscan2
- ADAMTS6 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as COSV100068214; called by muse, mutect2, varscan2
- AKAP12 | c.3872G>T p.G1291V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1427902553, COSV99482237; called by muse, mutect2, varscan2
- ATP11B | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100017451; called by muse, mutect2
- ATP6V0A4 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV100022515; called by muse, mutect2, varscan2
- AXDND1 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100858232, COSV100858272; called by muse, mutect2, varscan2
- BPIFB2 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99401063; called by muse, mutect2, varscan2
- CES4A | c.995del p.L332Wfs*4 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as COSV58654337; called by mutect2, pindel, varscan2
- CHTF18 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs763320442, COSV99135561; called by muse, mutect2, varscan2
- COL11A1 | c.4387C>T p.P1463S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100614695; called by muse, mutect2, varscan2
- COL11A1 | c.2908G>T p.G970* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100614697; called by muse, mutect2, varscan2
- COL21A1 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99777130; called by muse, mutect2, varscan2
- COL4A6 | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563155; called by muse, mutect2, varscan2
- COL9A1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs777952773, COSV100295036, COSV57883926; called by muse, mutect2, varscan2
- CWH43 | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV99892653; called by muse, mutect2, varscan2
- DOCK9 | c.3236C>T p.P1079L (on ENST00000376460 / NM_001366676.2; = p.P1080L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs775117075, COSV59644700; called by muse, mutect2, varscan2
- DSC3 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs779053546, COSV100844420; called by muse, mutect2, varscan2
- DSG4 | c.116C>A p.T39K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100355202; called by muse, mutect2, varscan2
- DST | c.1490T>A p.L497H (on ENST00000361203 / NM_001374722.1; = p.L171H on NM_001723.6) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99750111; called by muse, mutect2, varscan2
- DUOX1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58479751; called by muse, mutect2, varscan2
- DUSP19 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100700191; called by muse, mutect2, varscan2
- EPHA7 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as rs1035177735, COSV65179262, COSV65185064, COSV65190393; called by muse, mutect2, varscan2
- ERBB4 | c.2566C>T p.H856Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100722655; called by muse, mutect2, varscan2
- ERC2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as COSV55604836, COSV99880146; called by muse, mutect2
- FAM120C | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557122168, COSV60261028; called by muse, mutect2
- FAT4 | c.11759T>C p.F3920S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.369); catalogued as COSV100627058; called by muse, mutect2, varscan2
- FBN1 | c.7937G>T p.C2646F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100353903; called by muse, mutect2, varscan2
- FBXW10 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs1461077428, COSV100111166; called by muse, mutect2, varscan2
- FKBP8 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99723816; called by muse, mutect2, varscan2
- FLG | c.11323G>A p.E3775K | Missense Mutation (SNP) | VAF 67/494 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.955); catalogued as rs750064713, COSV64235815, COSV64240389; called by muse, mutect2, varscan2
- FSCB | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs200714637, COSV61219384; called by muse, mutect2, varscan2
- GABRD | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV101059501; called by muse, mutect2
- GCN1 | c.7888C>T p.Q2630* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100324540; called by muse, mutect2, varscan2
- GOLIM4 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs374445265; called by muse, mutect2
- GRIN3A | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs79468186, COSV100701329; called by muse, mutect2, varscan2
- HAUS3 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as rs1408927482, COSV54723852, COSV99704117; called by muse, mutect2
- HEXD | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100027521; called by muse, mutect2, varscan2
- HTR6 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99229827; called by muse, mutect2, varscan2
- IGSF1 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV100811767; called by muse, mutect2, varscan2
- IL2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756737575, COSV56985338, COSV56986744; called by muse, mutect2
- ITGAL | c.2508G>A p.K836= | Splice Region (SNP) | VAF 21/90 reads (23%) | catalogued as COSV63324365; called by muse, mutect2, varscan2
- KIF26B | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100831501; called by muse, mutect2
- KMT2E | c.4408C>T p.P1470S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.071); catalogued as COSV99995677; called by muse, mutect2, varscan2
- KRT85 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as rs138267130; called by muse, mutect2, varscan2
- KTN1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101254931, COSV68022765; called by muse, mutect2, varscan2
- MAB21L1 | c.582G>T p.W194C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100076182; called by muse, mutect2, varscan2
- MAGEA3 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV100938988, COSV64755810; called by muse, mutect2, varscan2
- MAGEA3 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs782534869, COSV100938986; called by muse, mutect2, varscan2
- MUC16 | c.25553C>T p.T8518I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as rs1295890922, COSV67456535, COSV67497663; called by muse, mutect2, varscan2
- MYCBP2 | c.13186G>A p.E4396K (on ENST00000357337; = p.E4434K on NM_015057.5) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100629000; called by muse, mutect2, varscan2
- MYH11 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1567718928, COSV55551142; called by muse, mutect2, varscan2
- MYH2 | c.5173C>T p.Q1725* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV55447329; called by muse, mutect2, varscan2
- MYRIP | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100218203; called by muse, mutect2, varscan2
- MYRIP | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100218205; called by muse, mutect2, varscan2
- NLN | c.323T>A p.F108Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101114080; called by muse, mutect2, varscan2
- NRK | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV99686420, COSV99686487; called by muse, mutect2, varscan2
- NYAP2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as rs780236043, COSV56017452; called by muse, mutect2, varscan2
- OR2A5 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101278646, COSV68738744; called by muse, mutect2, varscan2
- OR2Z1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV100136312; called by muse, mutect2
- OR5H14 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs867052972, COSV101454051; called by muse, mutect2, varscan2
- OR5L1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61733704; called by muse, mutect2, varscan2
- PDCL2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99823811; called by muse, mutect2
- PLEKHG6 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99164035; called by muse, mutect2, varscan2
- POLM | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs932162239, COSV99641609; called by muse, mutect2, varscan2
- PRAME | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101286997; called by muse, mutect2, varscan2
- PRMT9 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.496); catalogued as COSV100481961; called by muse, mutect2, varscan2
- PSG9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52485385; called by muse, mutect2, varscan2
- RAB29 | c.542T>G p.I181S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99352887; called by muse, mutect2, varscan2
- RALA | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs1314503939, COSV99143321; called by muse, mutect2, varscan2
- RFC3 | c.386T>G p.F129C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101197786; called by muse, mutect2, varscan2
- RP1L1 | c.6971G>A p.R2324K | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as rs369143580; called by muse, mutect2, varscan2
- SH3GL2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs757525551, COSV101013969; called by muse, mutect2, varscan2
- SLC12A9 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.37); catalogued as rs747322913, COSV51935312; called by muse, mutect2, varscan2
- SLC25A52 | c.370C>T p.R124C (on ENST00000672005; = p.R114C on NM_001034172.4) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs768808547, COSV52504358; called by muse, mutect2, varscan2
- SLC44A5 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138689403, COSV63758541; called by muse, mutect2, varscan2
- SLC9C2 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV62943679, COSV62944653; called by muse, mutect2, varscan2
- SMARCC1 | c.3065C>T p.S1022F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV99592152; called by muse, mutect2, varscan2
- SMG7 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs1426401806, COSV100750011; called by muse, mutect2, varscan2
- SNCAIP | c.1961A>T p.K654M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1260767296, COSV99746795; called by muse, mutect2, varscan2
- SPATA31A1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs1378616728; called by mutect2, varscan2
- ST3GAL2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.015); catalogued as COSV61596511; called by muse, mutect2, varscan2
- SULT1C4 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV99731434; called by muse, varscan2
- SUOX | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1288014224; called by muse, mutect2
- TBC1D28 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV100560889; called by muse, mutect2
- TECRL | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV101168296, COSV67089450; called by muse, mutect2, varscan2
- THYN1 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 50/228 reads (22%) | catalogued as rs149874205; called by muse, mutect2, varscan2
- TMPRSS2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771209150, COSV100151031; called by muse, mutect2, varscan2
- TPR | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.037); catalogued as COSV100823569; called by muse, mutect2, varscan2
- TRPV5 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs370556586; called by muse, mutect2, varscan2
- TSPAN7 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99730180; called by mutect2, varscan2
- TTN | c.67277G>A p.G22426E (on ENST00000591111; = p.G15002E on NM_003319.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | PolyPhen benign (0.038); catalogued as COSV100589376, COSV60127735; called by muse, mutect2, varscan2
- UGT1A9 | c.669T>A p.F223L | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV100691667; called by muse, mutect2, varscan2
- USP25 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.053); catalogued as COSV99583025; called by muse, mutect2, varscan2
- UTP15 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99707525; called by muse, mutect2, varscan2
- VPS28 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as rs1554876037, COSV52872660; called by muse, mutect2, varscan2
- ZC3H4 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763247562, COSV99451624; called by muse, mutect2, varscan2
- ZC3H4 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183786724, COSV99451626; called by muse, mutect2, varscan2
- ZCCHC4 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1400940338, COSV100254976; called by muse, mutect2, varscan2
- ZNF345 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs368732049; called by muse, varscan2
- ZNF345 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100080112; called by muse, varscan2
- ZNF492 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV101513926; called by muse, mutect2, varscan2
- ZNF557 | c.1012G>A p.E338K (on ENST00000414706 / NM_001044388.2; = p.E345K on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866560150, COSV99422192; called by muse, mutect2, varscan2
- A1CF | c.534C>T p.N178= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV99255121; called by muse, mutect2, varscan2
- ADGRE2 | c.129C>T p.T43= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as rs762040959, COSV100215618; called by muse, mutect2
- ADGRL3 | c.912G>A p.R304= (on ENST00000506720 / NM_001322402.2; = p.R236= on NM_015236.6) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV72273261; called by muse, mutect2, varscan2
- AL592490.1 | c.2700C>T p.S900= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101308073, COSV101308318; called by muse, mutect2, varscan2
- ATP6V0A4 | c.627G>A p.E209= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100022516; called by muse, mutect2, varscan2
- BMP1 | c.1098C>T p.S366= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1273304412, COSV100108934; called by muse, mutect2, varscan2
- BPIFB2 | c.1026G>A p.E342= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV50064564, COSV99401062; called by muse, mutect2, varscan2
- CPNE2 | c.331C>T p.L111= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99321162; called by muse, mutect2, varscan2
- DESI2 | c.534C>T p.S178= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs760496720, COSV99797872; called by muse, mutect2
- DUOX2 | c.2970G>T p.L990= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1248677306, COSV66532670, COSV66533282; called by muse, mutect2, varscan2
- DUOX2 | c.2302C>T p.L768= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101199532; called by muse, mutect2, varscan2
- DUOX2 | c.2301C>T p.I767= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV66533410; called by muse, mutect2, varscan2
- EDC3 | c.699C>T p.S233= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV59339282; called by muse, mutect2, varscan2
- FANCG | c.228C>T p.N76= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101072907; called by muse, mutect2, varscan2
- FBXO40 | c.2034G>A p.P678= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs372791958; called by muse, mutect2, varscan2
- FCRL5 | c.1509C>T p.I503= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV62518558; called by muse, mutect2, varscan2
- FGG | c.513C>T p.I171= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100271649; called by muse, mutect2, varscan2
- FLNC | c.1278G>A p.V426= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as COSV100367536; called by muse, mutect2, varscan2
- GDPD1 | c.735C>T p.S245= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99404756; called by muse, mutect2, varscan2
- GPR158 | c.1116G>A p.R372= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV66269325; called by muse, mutect2, varscan2
- GRN | c.1539C>T p.H513= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs772977073, COSV50007977; called by muse, mutect2, varscan2
- HELQ | c.3138C>T p.L1046= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs768787457, COSV55026412, COSV55026723; called by muse, mutect2, varscan2
- HEXD | c.336C>T p.P112= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100027523; called by muse, mutect2, varscan2
- HTR6 | c.894C>T p.S298= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs202204432, COSV99229821; called by muse, mutect2, varscan2
- IGKV3-20 | c.267G>A p.G89= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- KALRN | c.2394C>T p.D798= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1207215684, COSV99561795; called by muse, mutect2, varscan2
- KLHL1 | c.210G>A p.K70= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV64772001, COSV64777184; called by muse, mutect2, varscan2
- LRP5 | c.1320C>T p.I440= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs745638620, COSV53720386; called by muse, mutect2, varscan2
- MUC16 | c.27996C>T p.S9332= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1481301357, COSV67467804; called by muse, mutect2, varscan2
- MYH11 | c.2571G>A p.K857= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs777096260, COSV100257496; called by muse, mutect2, varscan2
- NCOA1 | c.3756G>A p.G1252= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99945014; called by muse, mutect2, varscan2
- NPAP1 | c.993G>A p.S331= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs1205066447, COSV61507865; called by muse, mutect2
- OR51V1 | c.471C>T p.F157= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs76139118; called by muse, varscan2
- OR5K2 | c.273G>A p.R91= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as COSV101415943, COSV101415960; called by muse, mutect2, varscan2
- OR6C74 | c.477G>A p.L159= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as rs1018534334, COSV100667639; called by muse, mutect2
- PAK3 | c.735C>T p.S245= (on ENST00000262836 / NM_001324328.2; = p.S230= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV99456298; called by muse, mutect2, varscan2
- PCDHB5 | c.1311G>A p.T437= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs782464724, COSV99167577; called by muse, mutect2, varscan2
- PCDHGA5 | c.1614G>A p.G538= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV99529098; called by muse, mutect2, varscan2
- PDZRN3 | c.1413C>T p.I471= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99726939; called by muse, mutect2, varscan2
- PLCH2 | c.435C>T p.T145= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99615358, COSV99617395; called by muse, mutect2, varscan2
- PSMD2 | c.1761C>T p.F587= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs957338442, COSV100031483; called by muse, mutect2, varscan2
- REST | c.462G>A p.S154= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs1007376860, COSV100470613; called by muse, mutect2, varscan2
- RGS7BP | c.87G>A p.Q29= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100470274; called by muse, mutect2, varscan2
- RYR2 | c.12648G>A p.A4216= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs781557399, COSV63659303; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SDK1 | c.3165G>A p.L1055= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101268658, COSV101269924; called by muse, mutect2, varscan2
- SMUG1 | c.291C>T p.P97= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99679274; called by muse, mutect2, varscan2
- TBC1D32 | c.1287C>T p.F429= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs548109381, COSV51556418; called by muse, mutect2, varscan2
- TLE6 | c.1479G>A p.Q493= (on ENST00000246112 / NM_001143986.2; = p.Q370= on NM_024760.3) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1210384527, COSV99503978; called by muse, mutect2, varscan2
- TMEM130 | c.945C>T p.I315= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV59558354; called by muse, mutect2, varscan2
- UNKL | c.306G>A p.R102= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100061160; called by muse, mutect2, varscan2
- WDR33 | c.2326C>T p.L776= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100459472; called by muse, mutect2, varscan2
- WNT6 | c.292C>T p.L98= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99293085; called by muse, mutect2
- ZFP37 | c.498A>G p.K166= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1421646819, COSV100953148; called by muse, mutect2, varscan2
- ZNF398 | c.459C>T p.S153= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs758144356, COSV100246794; called by muse, mutect2, varscan2
- ZNF648 | c.168G>A p.R56= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100374394; called by muse, mutect2, varscan2
- ARHGEF11 | c.4511-132G>A | Intron (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100168165; called by muse, mutect2
- FAM86C1P | n.324G>A | RNA (SNP) | VAF 10/97 reads (10%) | catalogued as COSV100660565; called by muse, mutect2, varscan2
- KCNK10 | c.38-7217G>A | Intron (SNP) | VAF 19/168 reads (11%) | catalogued as COSV100067118; called by muse, mutect2, varscan2
- MIR381 | n.46G>A | RNA (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- MIR498 | n.37C>T | RNA (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- MIRLET7C | n.61C>A | RNA (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PDE4B | c.281+74239C>G | Intron (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100301919; called by muse, mutect2, varscan2
- PRTFDC1 | c.339+28609G>A | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100196662, COSV100197071; called by muse, mutect2, varscan2
